Somatic mutation profile of tumor specimen MMRF_2089_1_BM_CD138pos (aliquot MMRF_2089_1_BM_CD138pos_T1_KHS5U_L08805) from MMRF case MMRF_2089, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 66.9 years (24,417 days).
Specimen MMRF_2089_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 22ec565c-12b5-4103-b812-e491f0552e8f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2089_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2089_1_PB_WBC_C3_KHS5U_L08822; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b7a200eb-91b2-4876-97ba-4f62931d5b70

The open-access MAF lists 248 somatic variants for this specimen: 92 protein-altering or splice-affecting, 29 silent, 127 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 74, 3'UTR 72, Silent 29, Intron 28, 5'UTR 9, 3'Flank 8, Nonsense Mutation 7, RNA 6, Frame Shift Del 6, 5'Flank 4, Frame Shift Ins 2, Splice Region 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.841G>A p.D281N | Missense Mutation (SNP) | VAF 28/78 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs764146326, CD137626, CM076566, CM153816, COSV52671054, COSV52674651, COSV52678614; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- ACAN | c.6701T>A p.L2234Q | Missense Mutation (SNP) | VAF 103/271 reads (38%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.977); catalogued as COSV100718699; called by muse, mutect2, varscan2
- ADAMTS2 | c.763C>T p.R255W | Missense Mutation (SNP) | VAF 42/182 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.328); catalogued as rs767850400, COSV99201369; called by muse, mutect2, varscan2
- ADGRD1 | c.1079A>G p.H360R | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.949); catalogued as rs746975895; called by muse, mutect2, varscan2
- APOA2 | c.277C>T p.L93F | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as rs1215900467; called by muse, mutect2, varscan2
- BTG1 | c.85A>T p.K29* | Nonsense Mutation (SNP) | VAF 41/85 reads (48%) | catalogued as COSV55458809; called by muse, varscan2
- C3orf20 | c.346C>A p.R116S | Missense Mutation (SNP) | VAF 51/221 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.018); catalogued as COSV53782269; called by muse, mutect2, varscan2
- C3orf62 | c.259G>C p.E87Q | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.628); catalogued as COSV55539998; called by muse, mutect2, varscan2
- CAT | c.1333G>A p.A445T | Missense Mutation (SNP) | VAF 37/126 reads (29%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs749536831; called by muse, mutect2, varscan2
- CDH7 | c.2245G>C p.D749H | Missense Mutation (SNP) | VAF 39/154 reads (25%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.606); catalogued as COSV59883694; called by muse, mutect2, varscan2
- CHP1 | c.580C>T p.L194F | Missense Mutation (SNP) | VAF 35/251 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100587184; called by muse, mutect2, varscan2
- COL27A1 | c.2512G>A p.G838S | Missense Mutation (SNP) | VAF 91/170 reads (54%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV61926137; called by muse, varscan2
- DFFA | c.526dup p.Q176Pfs*5 | Frame Shift Ins (INS) | VAF 27/92 reads (29%) | catalogued as rs755703182; called by mutect2, pindel, varscan2
- FASTKD3 | c.1756G>A p.D586N | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.91); catalogued as COSV52949773; called by muse, mutect2, varscan2
- FLG | c.2561G>T p.G854V | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as rs373305550; called by muse, varscan2
- GMPR | c.179C>T p.T60M | Missense Mutation (SNP) | VAF 29/162 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1162015376; called by muse, mutect2, varscan2
- GRIP1 | c.-420+7G>A | Splice Region (SNP) | VAF 9/225 reads (4%) | catalogued as rs1163053882; called by muse, mutect2
- IGHV2-70 | c.310A>T p.T104S | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (1); PolyPhen probably damaging (0.989); catalogued as rs368647772; called by muse, varscan2
- IGHV2-70 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.876); catalogued as rs534553794; called by muse, varscan2
- IGLV3-1 | c.97C>G p.P33A | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT tolerated (0.76); PolyPhen benign (0.166); catalogued as rs573884769; called by muse, mutect2, varscan2
- MAGEL2 | c.3559C>T p.R1187* | Nonsense Mutation (SNP) | VAF 48/136 reads (35%) | catalogued as rs368965952, COSV100045884, COSV100046025; called by muse, mutect2, varscan2
- MAP1A | c.2592G>C p.K864N | Missense Mutation (SNP) | VAF 26/202 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100288595; called by muse, mutect2, varscan2
- MUC12 | c.394C>T p.L132F | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated, low confidence (0.06); catalogued as rs1256983713; called by muse, mutect2, varscan2
- NUP214 | c.3295C>T p.R1099W | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1303316975; called by muse, mutect2, varscan2
- PPP1R3C | c.60G>A p.M20I | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as rs765370918; called by muse, mutect2, varscan2
- RINL | c.1499T>C p.F500S (on ENST00000591812 / NM_001195833.2; = p.F386S on NM_198445.4) | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758854340; called by muse, varscan2
- SVOPL | c.434C>T p.T145M | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.69); catalogued as rs139868586; called by mutect2, varscan2
- TRABD | c.672C>T p.S224= | Splice Region (SNP) | VAF 27/61 reads (44%) | catalogued as rs763947053; called by muse, mutect2, varscan2
- TRRAP | c.5867C>T p.T1956I (on ENST00000359863 / NM_001244580.1; = p.T1938I on NM_003496.3) | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.067); catalogued as rs782485850; called by muse, mutect2, varscan2
- UEVLD | c.305A>G p.H102R | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1308377012; called by muse, mutect2, varscan2
- WNK3 | c.3440C>T p.S1147F | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV63614176; called by muse, mutect2, varscan2
- ZFHX3 | c.7882G>A p.E2628K | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); catalogued as rs762362472, COSV51712740; called by muse, mutect2, varscan2
- ZNF679 | c.1210G>T p.G404* | Nonsense Mutation (SNP) | VAF 29/152 reads (19%) | catalogued as COSV55378362; called by muse, mutect2, varscan2
- ZNF679 | c.1211G>T p.G404V | Missense Mutation (SNP) | VAF 29/152 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99738433; called by muse, mutect2, varscan2
- ZNF7 | c.851G>A p.G284E | Missense Mutation (SNP) | VAF 92/131 reads (70%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.874); catalogued as rs1319987786; called by muse, mutect2, varscan2
- ACSM2B | c.383G>T p.R128L | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- B4GALT6 | c.354C>A p.F118L | Missense Mutation (SNP) | VAF 74/137 reads (54%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- CAPRIN2 | c.479A>G p.Q160R | Missense Mutation (SNP) | VAF 20/151 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CATSPERG | c.1839G>A p.M613I | Missense Mutation (SNP) | VAF 57/202 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- CD207 | c.122C>G p.T41R | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.387); called by muse, mutect2, varscan2
- CEP152 | c.1387A>T p.S463C | Missense Mutation (SNP) | VAF 25/154 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- CLK3 | c.1750C>T p.L584F (on ENST00000395066 / NM_001130028.1; = p.L436F on NM_003992.4) | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- CMYA5 | c.9854A>T p.K3285M | Missense Mutation (SNP) | VAF 42/198 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- CTNNA2 | c.1286T>A p.V429E | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); called by muse, varscan2
- CTSV | c.113G>A p.R38K | Missense Mutation (SNP) | VAF 39/145 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CTTNBP2 | c.1595A>G p.H532R | Missense Mutation (SNP) | VAF 26/199 reads (13%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- DPYSL3 | c.619C>T p.Q207* | Nonsense Mutation (SNP) | VAF 8/34 reads (24%) | called by muse, mutect2, varscan2
- DSC2 | c.1109A>C p.D370A | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- DUSP7 | c.419C>T p.T140M | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- F13A1 | c.1676C>T p.T559I | Missense Mutation (SNP) | VAF 25/155 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- FBXO11 | c.1575T>A p.F525L (on ENST00000403359 / NM_001190274.2; = p.F441L on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.495); called by muse, mutect2
- FRYL | c.1204A>G p.T402A | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- FUT6 | c.289A>T p.K97* | Nonsense Mutation (SNP) | VAF 38/271 reads (14%) | called by muse, mutect2, varscan2
- HEATR5A | c.451C>T p.Q151* | Nonsense Mutation (SNP) | VAF 31/90 reads (34%) | called by muse, mutect2, varscan2
- HK1 | c.1265A>G p.Q422R | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT tolerated (0.88); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- HLA-DPB1 | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 39/144 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- IGHV2-70D | c.347G>A p.C116Y | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- IGKV4-1 | c.136del p.S46Afs*14 | Frame Shift Del (DEL) | VAF 20/40 reads (50%) | called by pindel, varscan2
- JMJD1C | c.5209A>G p.I1737V | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- KBTBD3 | c.1516C>A p.P506T | Missense Mutation (SNP) | VAF 45/135 reads (33%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- KLHDC7B | c.1573C>T p.P525S (on ENST00000395676; = p.P1166S on NM_138433.5) | Missense Mutation (SNP) | VAF 51/135 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.183); called by muse, mutect2, varscan2
- LRTOMT | c.125del p.K42Sfs*9 | Frame Shift Del (DEL) | VAF 15/55 reads (27%) | called by mutect2, pindel, varscan2
- LRWD1 | c.1625T>G p.V542G | Missense Mutation (SNP) | VAF 73/192 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- MACROD1 | c.930C>A p.D310E | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- NARF | c.688G>A p.D230N | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NFIA | c.556G>A p.A186T | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.6); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- NYAP1 | c.592del p.R198Gfs*5 | Frame Shift Del (DEL) | VAF 31/179 reads (17%) | called by mutect2, pindel, varscan2
- OSMR | c.797G>A p.G266E | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- PKHD1L1 | c.12017G>A p.S4006N | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PNLIP | c.887G>A p.G296D | Missense Mutation (SNP) | VAF 39/253 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- POU4F3 | c.41C>G p.P14R | Missense Mutation (SNP) | VAF 31/147 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- PYDC2 | c.281T>C p.M94T | Missense Mutation (SNP) | VAF 77/321 reads (24%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RAB11FIP3 | c.835G>A p.V279I | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RALGAPA2 | c.3016_3017del p.N1006* | Frame Shift Del (DEL) | VAF 4/38 reads (11%) | called by mutect2, pindel, varscan2
- RGSL1 | c.626A>G p.H209R | Missense Mutation (SNP) | VAF 98/156 reads (63%) | SIFT tolerated (0.74); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- RILPL2 | c.149G>C p.R50P | Missense Mutation (SNP) | VAF 66/215 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- RINL | c.1504dup p.A502Gfs*51 (on ENST00000591812 / NM_001195833.2; = p.A388Gfs*51 on NM_198445.4) | Frame Shift Ins (INS) | VAF 18/70 reads (26%) | called by pindel, varscan2
- SCN5A | c.33C>G p.S11R | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- SERPINB1 | c.880C>T p.Q294* | Nonsense Mutation (SNP) | VAF 113/183 reads (62%) | called by muse, mutect2, varscan2
- SIAH2 | c.257A>C p.Y86S | Missense Mutation (SNP) | VAF 53/195 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- SRRM4 | c.1393G>A p.E465K | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- SRRM5 | c.361G>C p.G121R | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TINF2 | c.37C>T p.R13C | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TIPARP | c.1948G>C p.E650Q | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); called by muse, varscan2
- TNS1 | c.4106C>T p.S1369F | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TP53 | c.894_910del p.E298Dfs*2 | Frame Shift Del (DEL) | VAF 37/138 reads (27%) | called by pindel, varscan2
- TSPAN19 | c.296T>C p.V99A | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.64); called by muse, mutect2, varscan2
- TYW1 | c.499del p.T167Lfs*3 | Frame Shift Del (DEL) | VAF 61/219 reads (28%) | called by mutect2, pindel, varscan2
- XPOT | c.1168A>G p.N390D | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZMYND11 | c.1327T>A p.L443I | Missense Mutation (SNP) | VAF 7/139 reads (5%) | SIFT tolerated (0.42); PolyPhen benign (0.03); called by muse, mutect2
- ZNF3 | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- ZSCAN32 | c.10G>T p.V4L (on ENST00000396846; = p.V5L on NM_001284527.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 53/157 reads (34%) | SIFT tolerated, low confidence (0.33); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- AHCTF1 | c.2196T>G p.P732= (on ENST00000366508; = p.P706= on NM_015446.5) | Silent (SNP) | VAF 8/36 reads (22%) | called by muse, mutect2, varscan2
- ANKRD27 | c.2352C>T p.A784= | Silent (SNP) | VAF 5/25 reads (20%) | called by muse, mutect2
- ANKRD53 | c.642C>G p.P214= | Silent (SNP) | VAF 29/117 reads (25%) | called by muse, mutect2, varscan2
- ATF3 | c.330G>A p.K110= | Silent (SNP) | VAF 21/97 reads (22%) | called by muse, mutect2, varscan2
- CDH8 | c.1830C>A p.V610= | Silent (SNP) | VAF 38/88 reads (43%) | catalogued as COSV54883946; called by muse, mutect2, varscan2
- CHRM4 | c.351C>T p.N117= | Silent (SNP) | VAF 46/201 reads (23%) | catalogued as rs200711711, COSV63126667; called by muse, mutect2, varscan2
- CUBN | c.5799T>A p.S1933= | Silent (SNP) | VAF 31/135 reads (23%) | called by muse, mutect2, varscan2
- CYFIP1 | c.2490C>T p.H830= | Silent (SNP) | VAF 52/265 reads (20%) | called by muse, mutect2, varscan2
- DDX58 | c.1029C>A p.I343= | Silent (SNP) | VAF 28/174 reads (16%) | called by muse, mutect2, varscan2
- DIP2C | c.2523G>T p.V841= | Silent (SNP) | VAF 52/153 reads (34%) | catalogued as rs573371081; called by muse, mutect2, varscan2
- ECPAS | c.2424C>T p.C808= | Silent (SNP) | VAF 37/132 reads (28%) | called by muse, mutect2, varscan2
- ESPL1 | c.3639C>T p.S1213= | Silent (SNP) | VAF 47/187 reads (25%) | catalogued as rs753840797; called by muse, mutect2, varscan2
- FBXL17 | c.732C>T p.D244= | Silent (SNP) | VAF 5/13 reads (38%) | called by muse, mutect2, varscan2
- GGT6 | c.732C>T p.G244= (on ENST00000574154 / NM_001122890.3; = p.G212= on NM_153338.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 25/68 reads (37%) | catalogued as rs373381271, COSV54593697; called by muse, mutect2, varscan2
- GML | c.88A>C p.R30= | Silent (SNP) | VAF 12/52 reads (23%) | called by mutect2, varscan2
- HEY1 | c.580C>T p.L194= | Silent (SNP) | VAF 33/117 reads (28%) | called by muse, mutect2, varscan2
- IGHV3-23 | c.24T>C p.L8= | Silent (SNP) | VAF 12/79 reads (15%) | catalogued as rs566916785; called by muse, varscan2
- IGKV4-1 | c.177A>G p.L59= | Silent (SNP) | VAF 28/43 reads (65%) | catalogued as rs551368026; called by muse, varscan2
- NSMCE1 | c.744G>A p.E248= | Silent (SNP) | VAF 31/104 reads (30%) | called by muse, mutect2, varscan2
- OR8B8 | c.591T>A p.L197= | Silent (SNP) | VAF 8/144 reads (6%) | called by muse, mutect2
- PCDHA8 | c.1629G>A p.P543= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as rs555722520, COSV65333069, COSV65333143; called by muse, varscan2
- PDK2 | c.336C>T p.F112= | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as COSV99143096; called by muse, mutect2
- PIH1D1 | c.18G>A p.L6= | Silent (SNP) | VAF 44/168 reads (26%) | catalogued as rs776406541; called by mutect2, varscan2
- PTCHD4 | c.729G>C p.L243= | Silent (SNP) | VAF 32/122 reads (26%) | called by muse, mutect2, varscan2
- SLC16A14 | c.1407A>G p.K469= | Silent (SNP) | VAF 16/35 reads (46%) | called by muse, mutect2, varscan2
- SORBS3 | c.1323G>A p.E441= | Silent (SNP) | VAF 26/72 reads (36%) | called by muse, mutect2, varscan2
- TRABD2A | c.841C>T p.L281= (on ENST00000409520 / NM_001277053.2; = p.L232= on NM_001080824.3) | Silent (SNP) | VAF 20/81 reads (25%) | called by muse, mutect2, varscan2
- TYK2 | c.1404C>T p.D468= | Silent (SNP) | VAF 14/80 reads (18%) | catalogued as rs374132564; called by muse, mutect2, varscan2
- ZC3H13 | c.3723G>T p.L1241= | Silent (SNP) | VAF 29/38 reads (76%) | called by muse, mutect2, varscan2
- AC093909.6 | n.93T>A | RNA (SNP) | VAF 32/136 reads (24%) | called by muse, mutect2, varscan2
- AKAP13 | c.*4150G>A | 3'UTR (SNP) | VAF 45/281 reads (16%) | called by muse, mutect2, varscan2
- ALG10B | c.172-97C>T | Intron (SNP) | VAF 28/96 reads (29%) | called by muse, mutect2, varscan2
- AMD1 | c.*1004G>C | 3'UTR (SNP) | VAF 9/26 reads (35%) | called by muse, mutect2, varscan2
- ANKRD31 | c.104+32C>A | Intron (SNP) | VAF 18/58 reads (31%) | called by muse, mutect2, varscan2
- ARHGEF5 | c.*460C>T | 3'UTR (SNP) | VAF 23/110 reads (21%) | called by muse, mutect2, varscan2
- BCL2 | c.*2491A>G | 3'UTR (SNP) | VAF 14/52 reads (27%) | catalogued as rs1009407487; called by muse, mutect2, varscan2
- C12orf29 | c.*1596dup | 3'UTR (INS) | VAF 13/74 reads (18%) | called by mutect2, varscan2
- C12orf65 | c.*84_*86del | 3'UTR (DEL) | VAF 14/76 reads (18%) | called by pindel, varscan2
- C1S | c.392-286C>T | Intron (SNP) | VAF 3/32 reads (9%) | called by muse, mutect2
- C2orf91 | n.2245A>G | RNA (SNP) | VAF 33/99 reads (33%) | called by muse, mutect2, varscan2
- C7 | c.*547C>A | 3'UTR (SNP) | VAF 7/39 reads (18%) | called by muse, mutect2, varscan2
- CAMK4 | c.*1968T>C | 3'UTR (SNP) | VAF 12/54 reads (22%) | called by muse, mutect2
- CCDC113 | c.*2042C>A | 3'UTR (SNP) | VAF 31/101 reads (31%) | called by muse, mutect2, varscan2
- CCNT1 | c.*2906A>C | 3'UTR (SNP) | VAF 8/100 reads (8%) | called by muse, mutect2
- CCNT2 | c.774+138C>T | Intron (SNP) | VAF 28/77 reads (36%) | called by muse, mutect2, varscan2
- CD1D | chr1:158177012 T>A | 5'Flank (SNP) | VAF 9/32 reads (28%) | called by muse, mutect2, varscan2
- CDC42SE2 | c.*2032A>G | 3'UTR (SNP) | VAF 12/56 reads (21%) | called by muse, mutect2, varscan2
- CDH19 | c.-16C>T | 5'UTR (SNP) | VAF 34/148 reads (23%) | called by muse, mutect2, varscan2
- CHAF1B | c.*215C>T | 3'UTR (SNP) | VAF 15/41 reads (37%) | catalogued as rs571857716; called by muse, mutect2, varscan2
- CHRNA4 | c.*503C>T | 3'UTR (SNP) | VAF 30/138 reads (22%) | called by muse, mutect2
- CLCN5 | chrX:50094843 G>C | 3'Flank (SNP) | VAF 9/33 reads (27%) | called by muse, mutect2, varscan2
- COL24A1 | c.*917G>C | 3'UTR (SNP) | VAF 35/129 reads (27%) | catalogued as rs1490456958; called by muse, mutect2, varscan2
- CPED1 | c.*190C>T | 3'UTR (SNP) | VAF 20/46 reads (43%) | called by muse, mutect2, varscan2
- CST5 | c.*32C>A | 3'UTR (SNP) | VAF 50/165 reads (30%) | called by muse, mutect2, varscan2
- CYFIP2 | chr5:157394442 G>A | 3'Flank (SNP) | VAF 25/109 reads (23%) | called by muse, mutect2, varscan2
- CYP2B7P | n.896G>T | RNA (SNP) | VAF 26/120 reads (22%) | called by muse, mutect2, varscan2
- DDX10 | c.2450+847A>G | Intron (SNP) | VAF 11/41 reads (27%) | called by muse, mutect2, varscan2
- DFFB | c.*1260A>G | 3'UTR (SNP) | VAF 25/83 reads (30%) | called by muse, mutect2, varscan2
- DLAT | c.*1123T>G | 3'UTR (SNP) | VAF 32/117 reads (27%) | called by muse, mutect2, varscan2
- DMRTC2 | c.*20G>T | 3'UTR (SNP) | VAF 17/62 reads (27%) | catalogued as rs1555837437; called by muse, mutect2, varscan2
- DNAJC18 | c.*1384A>G | 3'UTR (SNP) | VAF 20/72 reads (28%) | called by muse, mutect2, varscan2
- DNMT1 | c.3475+22C>T | Intron (SNP) | VAF 18/124 reads (15%) | called by muse, mutect2, varscan2
- DOCK5 | c.3816+800G>T | Intron (SNP) | VAF 11/35 reads (31%) | called by muse, mutect2, varscan2
- EFCAB13 | c.2638+230T>G | Intron (SNP) | VAF 9/29 reads (31%) | called by muse, mutect2, varscan2
- EHMT1 | c.*197G>C | 3'UTR (SNP) | VAF 33/117 reads (28%) | called by muse, mutect2, varscan2
- ELP1 | c.650-43A>T | Intron (SNP) | VAF 29/50 reads (58%) | called by muse, mutect2, varscan2
- EMX2 | c.*370G>T | 3'UTR (SNP) | VAF 48/145 reads (33%) | called by muse, mutect2, varscan2
- EN2 | c.*851C>G | 3'UTR (SNP) | VAF 26/108 reads (24%) | called by muse, mutect2, varscan2
- F2RL2 | c.*228C>A | 3'UTR (SNP) | VAF 15/51 reads (29%) | called by muse, mutect2, varscan2
- FAM189A1 | c.*125C>T | 3'UTR (SNP) | VAF 40/181 reads (22%) | called by muse, mutect2, varscan2
- FAM98B | c.*1266_*1278del | 3'UTR (DEL) | VAF 6/76 reads (8%) | called by mutect2, pindel
- FCER1G | c.*43C>T | 3'UTR (SNP) | VAF 77/325 reads (24%) | called by muse, mutect2, varscan2
- FKBP7 | c.*1845dup | 3'UTR (INS) | VAF 32/102 reads (31%) | called by mutect2, varscan2
- FOXRED1 | c.*173C>A | 3'UTR (SNP) | VAF 23/96 reads (24%) | catalogued as rs1478624812; called by muse, mutect2, varscan2
- FTO | c.*1800G>A | 3'UTR (SNP) | VAF 4/10 reads (40%) | called by muse, mutect2, varscan2
- GABARAP | c.-119G>A | 5'UTR (SNP) | VAF 23/60 reads (38%) | catalogued as rs976912366; called by muse, varscan2
- GALC | c.195+536G>A | Intron (SNP) | VAF 8/96 reads (8%) | called by muse, mutect2
- GAREM1 | c.*389C>T | 3'UTR (SNP) | VAF 23/107 reads (21%) | called by muse, mutect2, varscan2
- GASK1A | c.-130C>T | 5'UTR (SNP) | VAF 28/84 reads (33%) | called by mutect2, varscan2
- GFOD1 | c.*6804C>T | 3'UTR (SNP) | VAF 32/125 reads (26%) | called by muse, mutect2, varscan2
- GIT2 | c.1732-40C>T | Intron (SNP) | VAF 63/224 reads (28%) | called by muse, mutect2, varscan2
- GNLY | chr2:85694320 G>C | 5'Flank (SNP) | VAF 19/98 reads (19%) | called by muse, mutect2, varscan2
- GNPTAB | c.*449T>A | 3'UTR (SNP) | VAF 23/86 reads (27%) | called by muse, mutect2, varscan2
- GULP1 | c.399+50G>T | Intron (SNP) | VAF 25/60 reads (42%) | called by muse, mutect2, varscan2
- HMGCLL1 | c.*657T>A | 3'UTR (SNP) | VAF 29/78 reads (37%) | catalogued as rs929250304; called by muse, mutect2, varscan2
- HS2ST1 | c.*792G>A | 3'UTR (SNP) | VAF 8/62 reads (13%) | called by muse, varscan2
- IGHV3-23 | c.-75C>T | 5'UTR (SNP) | VAF 6/33 reads (18%) | called by muse, mutect2, varscan2
- KANSL1 | c.1289+63A>T | Intron (SNP) | VAF 15/96 reads (16%) | called by muse, mutect2, varscan2
- KBTBD12 | c.*3366G>A | 3'UTR (SNP) | VAF 15/32 reads (47%) | called by muse, mutect2, varscan2
- KBTBD4 | c.*128C>T | 3'UTR (SNP) | VAF 7/53 reads (13%) | called by muse, mutect2, varscan2
- KCNMB1 | c.*416T>C | 3'UTR (SNP) | VAF 14/69 reads (20%) | called by muse, mutect2, varscan2
- LARP6 | c.200+1851C>A | Intron (SNP) | VAF 33/187 reads (18%) | called by muse, mutect2, varscan2
- LINC01644 | n.507C>G | RNA (SNP) | VAF 57/170 reads (34%) | called by muse, mutect2, varscan2
- LOXHD1 | c.*63G>A | 3'UTR (SNP) | VAF 27/115 reads (23%) | called by muse, mutect2, varscan2
- LRRC8E | c.-5-64C>A | Intron (SNP) | VAF 18/133 reads (14%) | catalogued as rs1181392763; called by muse, mutect2, varscan2
- LUZP2 | c.*3058A>T | 3'UTR (SNP) | VAF 13/54 reads (24%) | called by mutect2, varscan2
- LY6G5C | c.346-885C>T | Intron (SNP) | VAF 36/142 reads (25%) | called by muse, mutect2, varscan2
- LYRM7 | c.*2306C>T | 3'UTR (SNP) | VAF 10/28 reads (36%) | called by muse, mutect2, varscan2
- MACC1 | chr7:20139144 G>C | 3'Flank (SNP) | VAF 9/76 reads (12%) | called by muse, mutect2, varscan2
- MATR3 | c.-157_-155del | 5'UTR (DEL) | VAF 7/21 reads (33%) | called by mutect2, varscan2
- MAU2 | c.*137C>G | 3'UTR (SNP) | VAF 47/299 reads (16%) | called by muse, mutect2, varscan2
- MFN2 | c.709-42C>A | Intron (SNP) | VAF 46/172 reads (27%) | catalogued as rs1181707568; called by muse, varscan2
- MOBP | chr3:39515256 G>T | 3'Flank (SNP) | VAF 34/93 reads (37%) | called by muse, mutect2, varscan2
- MTRF1L | c.*2484del | 3'UTR (DEL) | VAF 82/267 reads (31%) | called by mutect2, pindel, varscan2
- MUC6 | c.*441G>A | 3'UTR (SNP) | VAF 19/93 reads (20%) | called by muse, mutect2, varscan2
- MVB12B | c.*2383G>T | 3'UTR (SNP) | VAF 15/27 reads (56%) | called by muse, mutect2, varscan2
- MYO3A | c.732-599C>T | Intron (SNP) | VAF 18/59 reads (31%) | called by muse, mutect2, varscan2
- MYO5C | c.4043-170C>T | Intron (SNP) | VAF 5/13 reads (38%) | called by muse, mutect2, varscan2
- NQO2 | chr6:3019858 G>C | 3'Flank (SNP) | VAF 5/25 reads (20%) | called by muse, mutect2
- NR2F2 | c.*2265G>T | 3'UTR (SNP) | VAF 7/44 reads (16%) | called by muse, mutect2, varscan2
- ONECUT2 | c.*11750dup | 3'UTR (INS) | VAF 13/46 reads (28%) | called by mutect2, varscan2
- OR4C50P | n.361A>T | RNA (SNP) | VAF 12/52 reads (23%) | catalogued as rs976980591; called by mutect2, varscan2
- PAPOLB | c.*1233A>G | 3'UTR (SNP) | VAF 12/67 reads (18%) | called by muse, mutect2, varscan2
- PAQR6 | c.760+39G>A | Intron (SNP) | VAF 27/103 reads (26%) | called by muse, mutect2, varscan2
- PDE4D | c.456-59882C>A | Intron (SNP) | VAF 23/111 reads (21%) | called by muse, mutect2, varscan2
- PDIA4 | c.*590G>A | 3'UTR (SNP) | VAF 51/183 reads (28%) | called by muse, mutect2, varscan2
- PDXK | c.142+3711C>G | Intron (SNP) | VAF 15/70 reads (21%) | called by muse, mutect2, varscan2
- PEG10 | c.*4798G>T | 3'UTR (SNP) | VAF 22/61 reads (36%) | called by muse, mutect2, varscan2
- PIGV | chr1:26798307 G>A | 3'Flank (SNP) | VAF 35/135 reads (26%) | called by muse, mutect2, varscan2
- PIK3R3 | c.*3382T>C | 3'UTR (SNP) | VAF 26/80 reads (33%) | called by muse, mutect2, varscan2
- PRKD1 | c.*714T>C | 3'UTR (SNP) | VAF 10/34 reads (29%) | called by muse, mutect2, varscan2
- PRKG1 | c.*2840C>T | 3'UTR (SNP) | VAF 35/142 reads (25%) | catalogued as rs1402167415; called by muse, mutect2, varscan2
- PTEN | c.*3989G>T | 3'UTR (SNP) | VAF 25/83 reads (30%) | called by muse, mutect2, varscan2
- RDH16 | c.*149C>G | 3'UTR (SNP) | VAF 33/122 reads (27%) | called by muse, mutect2, varscan2
- RHBG | chr1:156367745 C>T | 5'Flank (SNP) | VAF 15/184 reads (8%) | called by muse, mutect2
- RN7SL209P | chr15:101772982 G>A | 3'Flank (SNP) | VAF 9/48 reads (19%) | called by muse, mutect2, varscan2
- RNF32 | c.684+1743A>G | Intron (SNP) | VAF 14/84 reads (17%) | catalogued as rs1012529631; called by muse, mutect2, varscan2
- RPS6KB1 | c.-38G>C | 5'UTR (SNP) | VAF 9/24 reads (38%) | called by muse, mutect2, varscan2
- SEMA4A | c.139+76G>A | Intron (SNP) | VAF 22/86 reads (26%) | called by muse, mutect2, varscan2
- SKP1 | c.457-241G>A | Intron (SNP) | VAF 61/206 reads (30%) | called by muse, mutect2, varscan2
- SLC17A6 | chr11:22338177 T>A | 5'Flank (SNP) | VAF 27/105 reads (26%) | called by muse, mutect2, varscan2
- SLC44A1 | c.*5794C>T | 3'UTR (SNP) | VAF 26/112 reads (23%) | catalogued as rs886283955; called by muse, mutect2, varscan2
- SLC5A12 | c.1153+726T>G | Intron (SNP) | VAF 35/59 reads (59%) | called by muse, mutect2, varscan2
- SMAD9 | c.*2054C>T | 3'UTR (SNP) | VAF 22/31 reads (71%) | called by muse, mutect2, varscan2
- SMARCAD1 | c.*28G>A | 3'UTR (SNP) | VAF 64/167 reads (38%) | catalogued as rs1255919349; called by muse, varscan2
- SMU1 | c.-34G>C | 5'UTR (SNP) | VAF 104/561 reads (19%) | called by muse, varscan2
- SMUG1 | c.285+507G>C | Intron (SNP) | VAF 26/107 reads (24%) | called by muse, mutect2, varscan2
- SNN | c.*393C>A | 3'UTR (SNP) | VAF 37/88 reads (42%) | called by muse, mutect2, varscan2
- SNX20 | chr16:50667419 C>A | 3'Flank (SNP) | VAF 60/159 reads (38%) | called by muse, mutect2, varscan2
- SNX3 | c.-68G>A | 5'UTR (SNP) | VAF 4/51 reads (8%) | catalogued as COSV57778029; called by muse, mutect2
- SP7 | c.*937C>T | 3'UTR (SNP) | VAF 51/87 reads (59%) | called by muse, mutect2, varscan2
- SPATA8 | n.259C>A | RNA (SNP) | VAF 13/93 reads (14%) | called by muse, mutect2, varscan2
- SPICE1 | c.*1336G>T | 3'UTR (SNP) | VAF 19/50 reads (38%) | called by muse, mutect2, varscan2
- SPX | c.*128C>T | 3'UTR (SNP) | VAF 41/100 reads (41%) | called by muse, mutect2, varscan2
- SYT10 | c.*124G>A | 3'UTR (SNP) | VAF 27/81 reads (33%) | called by muse, mutect2, varscan2
- TLL1 | c.*2705C>A | 3'UTR (SNP) | VAF 26/69 reads (38%) | called by muse, mutect2, varscan2
- TMEM132D | c.-48G>A | 5'UTR (SNP) | VAF 25/96 reads (26%) | called by muse, mutect2, varscan2
- TMTC4 | c.778-75G>T | Intron (SNP) | VAF 20/26 reads (77%) | called by muse, mutect2, varscan2
- TPD52L3 | c.*1321G>T | 3'UTR (SNP) | VAF 19/90 reads (21%) | called by muse, mutect2, varscan2
- TSC1 | c.*3619G>T | 3'UTR (SNP) | VAF 67/226 reads (30%) | called by muse, mutect2, varscan2
- UBE2Q1 | c.*49A>G | 3'UTR (SNP) | VAF 54/230 reads (23%) | catalogued as rs754611046; called by muse, mutect2, varscan2
- USF3 | c.*5843C>T | 3'UTR (SNP) | VAF 8/40 reads (20%) | catalogued as rs1158333276; called by muse, mutect2, varscan2
- USP35 | c.*191A>T | 3'UTR (SNP) | VAF 22/106 reads (21%) | called by muse, mutect2, varscan2
- VCL | c.*702C>A | 3'UTR (SNP) | VAF 23/118 reads (19%) | catalogued as rs1413314403; called by muse, mutect2, varscan2
- VGLL3 | c.*3330G>A | 3'UTR (SNP) | VAF 31/123 reads (25%) | called by muse, mutect2, varscan2
- ZNF813 | c.*3433T>A | 3'UTR (SNP) | VAF 21/82 reads (26%) | called by muse, mutect2, varscan2
